Somatic mutation profile of tumor specimen TCGA-DE-A4MB-01A (aliquot TCGA-DE-A4MB-01A-11D-A257-08) from TCGA case TCGA-DE-A4MB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 79.4 years (29,011 days).
Specimen TCGA-DE-A4MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b52fe024-eb14-4af1-ad77-39bb8d12f637.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A4MB-10A (Blood Derived Normal), aliquot TCGA-DE-A4MB-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7efae010-82cc-4f9d-b93c-0f7d52fc7ff2

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62572203, COSV62573812; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC158 | c.3038A>G p.N1013S | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs201687534, COSV101187162; called by muse, mutect2, varscan2
- CDH26 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99721756, COSV99721851; called by muse, mutect2, varscan2
- COL5A3 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs148469753; called by muse, mutect2, varscan2
- CRYL1 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.509); catalogued as COSV100004172; called by muse, mutect2, varscan2
- DCAF4L1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs973927928, COSV60786385; called by muse, mutect2, varscan2
- EPG5 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs766875773, COSV56348725; called by muse, mutect2, varscan2
- FBXO9 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99762258; called by muse, mutect2, varscan2
- FMO3 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100882402, COSV63008041; called by muse, mutect2, varscan2
- IQUB | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs1489210500, COSV100226782; called by muse, mutect2, varscan2
- MIB2 | c.934A>T p.S312C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100598726; called by muse, mutect2, varscan2
- PKM | c.1193T>A p.L398H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100064527; called by mutect2, varscan2
- RBL1 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100726889; called by muse, mutect2
- SLC39A12 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66198199; called by muse, mutect2
- ZBTB8OS | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV100542145, COSV100542373; called by muse, mutect2, varscan2
- AP4E1 | c.1695G>T p.A565= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs528918348, COSV55914962, COSV99956316; called by muse, mutect2, varscan2
- CPSF1 | c.1332G>A p.E444= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100574244; called by muse, mutect2, varscan2
- CSMD2 | c.6198G>C p.R2066= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99586510; called by muse, mutect2, varscan2
- FGF13 | c.423C>T p.C141= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100263682; called by muse, mutect2, varscan2
- PRLHR | c.825C>T p.R275= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99492670; called by muse, mutect2, varscan2
- SLC2A1 | c.618C>T p.F206= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100995788; called by muse, mutect2
- SPOCK2 | c.576C>T p.A192= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs755295655, COSV100436316; called by muse, varscan2
